Somatic mutation profile of tumor specimen TCGA-L5-A891-01A (aliquot TCGA-L5-A891-01A-11D-A36J-09) from TCGA case TCGA-L5-A891, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: GX; Age at diagnosis: 51.8 years (18,925 days).
Specimen TCGA-L5-A891-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bc54870-5b36-463e-9077-28ce9192cad1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A891-11A (Solid Tissue Normal), aliquot TCGA-L5-A891-11A-21D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2581243-682e-4dfe-b1a8-1b10eb00ceee

The open-access MAF lists 173 somatic variants for this specimen: 137 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 32, Nonsense Mutation 11, Frame Shift Del 5, In Frame Del 2, 3'Flank 1, Intron 1, RNA 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 12/14 reads (86%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs139879505; called by muse, mutect2, varscan2
- ASB6 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs1367585867, COSV99475721; called by muse, mutect2, varscan2
- ASTN2 | c.1651C>T p.R551C (on ENST00000313400 / NM_001365069.1; = p.R500C on NM_014010.5) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776841753, COSV57773431; called by muse, mutect2, varscan2
- ATF7 | c.998G>A p.R333Q (on ENST00000548446 / NM_001366555.2; = p.R322Q on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753884312; called by muse, mutect2, varscan2
- ATG2A | c.5351G>A p.R1784Q | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752799001, COSV65965932; called by muse, mutect2, varscan2
- BRD1 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs759531800; called by muse, mutect2, varscan2
- CCDC198 | c.137C>G p.S46* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV53603921; called by muse, mutect2, varscan2
- CCDC81 | c.558G>T p.R186S (on ENST00000445632 / NM_001156474.2; = p.R96S on NM_021827.4) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53576471; called by muse, mutect2, varscan2
- CCT8L2 | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV63461850; called by muse, mutect2, varscan2
- CD109 | c.2948C>G p.S983C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99753746; called by muse, mutect2, varscan2
- CFAP221 | c.1906T>G p.S636A | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); catalogued as COSV99732061; called by muse, mutect2, varscan2
- CHST15 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753436566, COSV60560851; called by muse, mutect2, varscan2
- CRB1 | c.860A>T p.N287I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.328); catalogued as COSV100958937, COSV66339069; called by muse, mutect2, varscan2
- CYP24A1 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539392099; called by muse, mutect2, varscan2
- DDR2 | c.2503G>A p.D835N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.052); catalogued as COSV63370736; called by muse, mutect2, varscan2
- DMD | c.2183T>C p.I728T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs192004962; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- DST | c.17623C>G p.R5875G (on ENST00000361203 / NM_001374722.1; = p.R3572G on NM_015548.5) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55040729; called by mutect2, varscan2
- DTL | c.2036G>A p.S679N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1283680626, COSV65342553; called by muse, mutect2, varscan2
- EYS | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs377622148, COSV100675758; called by muse, mutect2, varscan2
- FBXL18 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs1343214954; called by muse, mutect2, varscan2
- FLT3 | c.979T>C p.Y327H | Missense Mutation (SNP) | VAF 55/64 reads (86%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV54043965; called by muse, mutect2, varscan2
- FZD9 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs371067074; called by muse, mutect2, varscan2
- GLCE | c.164G>C p.R55T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.017); catalogued as rs775089643; called by muse, mutect2, varscan2
- HAUS5 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.186); catalogued as rs188926778; called by mutect2, varscan2
- HCN1 | c.2312C>T p.T771M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100299249, COSV100301532; called by muse, mutect2, varscan2
- KCNA4 | c.1609G>T p.G537C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60252487; called by muse, mutect2, varscan2
- KCNG1 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs916410355; called by muse, varscan2
- KLK1 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs887144278; called by muse, mutect2
- LCE2C | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV64228491, COSV64228610; called by muse, mutect2, varscan2
- LTF | c.1852G>A p.V618M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1010790612, COSV51612724; called by muse, mutect2, varscan2
- MAOA | c.561C>G p.H187Q | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV58642400, COSV58643545; called by muse, mutect2, varscan2
- MDN1 | c.11956C>T p.R3986W | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as rs758141269; called by muse, mutect2, varscan2
- MUC5B | c.16243G>A p.V5415M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs895570250; called by muse, mutect2, varscan2
- MYOM2 | c.2813C>T p.A938V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.169); catalogued as rs186389832, COSV50708585; called by muse, mutect2, varscan2
- NES | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV104427524; called by muse, mutect2, varscan2
- NLRP13 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs565649099, COSV100738195, COSV61620577; called by muse, mutect2, varscan2
- OLFML2B | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.15); catalogued as rs762409288, COSV54196282; called by muse, mutect2, varscan2
- OR5D14 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 32/69 reads (46%) | catalogued as COSV59455703; called by muse, varscan2
- PAOX | c.1171A>T p.M391L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs1167907763; called by muse, varscan2
- PDZD2 | c.2003C>T p.T668M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs375591884; called by muse, mutect2, varscan2
- PHF13 | c.310A>G p.S104G | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs1196945533; called by muse, mutect2, varscan2
- PHF21B | c.1440C>A p.D480E | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV100503429; called by muse, mutect2, varscan2
- PLIN3 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.08); catalogued as rs142986276; called by muse, mutect2, varscan2
- RBM10 | c.1831G>T p.E611* | Nonsense Mutation (SNP) | VAF 33/39 reads (85%) | catalogued as COSV61308183; called by muse, mutect2, varscan2
- RBMXL2 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs376176065; called by muse, mutect2, varscan2
- RBP3 | c.1819C>A p.L607M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as rs1555211343; called by muse, mutect2, varscan2
- SCN9A | c.5123T>G p.L1708R (on ENST00000303354; = p.L1697R on NM_002977.3) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57599454, COSV57620411; called by muse, mutect2, varscan2
- SFMBT2 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV62813174; called by muse, mutect2, varscan2
- SLCO5A1 | c.2242G>A p.V748I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as rs376766213; called by muse, mutect2, varscan2
- TAOK1 | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV55594796; called by muse, mutect2, varscan2
- TGIF2LX | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 73/86 reads (85%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as rs764080796; called by muse, mutect2, varscan2
- TRANK1 | c.3302T>C p.I1101T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1226310866; called by muse, mutect2, varscan2
- TRIP10 | c.1513G>A p.A505T (on ENST00000313244 / NM_001288962.2; = p.A449T on NM_004240.4) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as rs780842925; called by muse, mutect2, varscan2
- TRPV4 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.2); catalogued as rs767169716, COSV55682549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.84223C>T p.Q28075* (on ENST00000591111; = p.Q20651* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV60011758; called by muse, mutect2, varscan2
- TTN | c.72460G>A p.V24154I (on ENST00000591111; = p.V16730I on NM_003319.4) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | PolyPhen benign (0.419); catalogued as rs928219120; called by muse, mutect2, varscan2
- TULP4 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV65571827; called by muse, mutect2, varscan2
- USP9X | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61070099; called by muse, mutect2, varscan2
- ZNF423 | c.1370C>T p.S457F (on ENST00000563137 / NM_001379286.1; = p.S449F on NM_015069.4) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV52180403; called by muse, mutect2, varscan2
- ZNF831 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs200797810, COSV64045762; called by muse, mutect2, varscan2
- ZNF85 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs566341045; called by muse, mutect2
- ZSCAN1 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as rs376247688, COSV56608196; called by mutect2, varscan2
- ADAMTSL1 | c.4759G>A p.D1587N | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- ANKRD30A | c.1006T>G p.S336A (on ENST00000611781; = p.S280A on NM_052997.2) | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.138); called by muse, mutect2
- ANO4 | c.2266T>C p.W756R (on ENST00000392977 / NM_001286615.2; = p.W721R on NM_178826.4) | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATP2B1 | c.1654C>T p.L552F | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BAZ2B | c.3374T>G p.L1125W | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BZW2 | c.1100T>C p.F367S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- C3AR1 | c.187C>A p.H63N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CARD8 | c.663C>G p.D221E (on ENST00000651546 / NM_001184900.3; = p.D171E on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- CASQ1 | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- CCDC86 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD48 | c.581A>G p.Y194C | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CDH17 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- CLINT1 | c.1273G>C p.D425H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CNTN6 | c.2087A>T p.K696I | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- DIDO1 | c.5584G>A p.E1862K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by mutect2, varscan2
- DYNC2H1 | c.3408G>T p.E1136D | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EOMES | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ETV5 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FANCG | c.1145T>A p.F382Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.193); called by muse, mutect2
- FBXL7 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- FOXD4L6 | c.1147T>A p.F383I | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- GLT1D1 | c.867T>G p.F289L (on ENST00000442111 / NM_001366889.1; = p.F209L on NM_144669.3) | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- IPO5 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- KCNH6 | c.2260T>G p.F754V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM2B | c.1832C>T p.T611M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1549L | c.2434A>T p.T812S (on ENST00000321505; = p.T1109S on NM_012194.3) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KMT5B | c.677T>A p.L226* | Nonsense Mutation (SNP) | VAF 40/77 reads (52%) | called by muse, mutect2, varscan2
- LHCGR | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- MAP1S | c.2789G>A p.G930E | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- MCM9 | c.638T>A p.V213D | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- MIGA1 | c.1125G>A p.M375I | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- MST1R | c.4095del p.S1366Afs*6 | Frame Shift Del (DEL) | VAF 8/83 reads (10%) | called by pindel, varscan2*
- NCEH1 | c.464del p.S155Mfs*24 (on ENST00000538775; = p.X123_splice on NM_020792.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 37/74 reads (50%) | called by mutect2, pindel, varscan2
- NEXMIF | c.882C>G p.Y294* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- NLRP3 | c.2035C>A p.L679M | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- NR4A2 | c.571del p.Q191Rfs*12 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | called by mutect2, pindel, varscan2
- NT5C1A | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- NUP43 | c.839G>A p.C280Y | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OMA1 | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR4K1 | c.337A>G p.M113V | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PACS1 | c.814_816del p.P272del | In Frame Del (DEL) | VAF 20/82 reads (24%) | called by mutect2, pindel, varscan2
- PBX3 | c.1066A>T p.S356C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PIP5K1C | c.624C>T p.N208= | Splice Region (SNP) | VAF 58/97 reads (60%) | called by muse, mutect2, varscan2
- PLXND1 | c.4292A>T p.E1431V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPN9 | c.760_784del p.V254Mfs*12 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | called by mutect2, pindel, varscan2
- PTPRD | c.1957G>C p.D653H | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2
- QSOX1 | c.628C>G p.H210D | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- RSRC2 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SEC16B | c.1912G>T p.A638S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- SEC61A1 | c.1405G>A p.G469S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- SLC17A4 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SLC7A1 | c.1840G>T p.D614Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMO | c.606C>A p.N202K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- SNTG2 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- SPTAN1 | c.863C>G p.A288G | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.238); called by muse, mutect2
- SUPT20HL2 | c.1288G>C p.A430P | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TAP2 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.747); called by muse, mutect2
- TAS1R2 | c.1184T>C p.V395A | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); called by muse, mutect2
- TBPL1 | c.343A>G p.I115V | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.167); called by muse, mutect2
- TCHHL1 | c.1892G>T p.G631V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TCTE1 | c.511A>G p.T171A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by mutect2, varscan2
- TEAD4 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TGM5 | c.2096A>T p.N699I (on ENST00000220420 / NM_201631.4; = p.N617I on NM_004245.4) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- TGM6 | c.1683G>C p.K561N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- TLN2 | c.6877G>T p.G2293* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- TMEM201 | c.484A>C p.K162Q | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAM1L1 | c.333C>G p.F111L | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TSC2 | c.988C>G p.P330A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- USH2A | c.11329C>A p.P3777T | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- WASHC5 | c.2447A>T p.E816V | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZCWPW1 | c.1604A>G p.N535S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZNF200 | c.1004_1042del p.I335_K347del | In Frame Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel
- ZNF367 | c.649_650del p.R217Sfs*81 | Frame Shift Del (DEL) | VAF 88/184 reads (48%) | called by mutect2, pindel, varscan2
- ALOX12B | c.1887G>A p.L629= | Silent (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- ARL4C | c.108C>T p.N36= | Silent (SNP) | VAF 20/73 reads (27%) | called by muse, mutect2, varscan2
- CBL | c.2349C>G p.A783= | Silent (SNP) | VAF 28/50 reads (56%) | called by muse, mutect2, varscan2
- CHD7 | c.8613T>C p.N2871= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1332141467, CX127515; called by muse, mutect2, varscan2
- CSTF2 | c.1386C>G p.A462= | Silent (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- DCAF5 | c.1329C>T p.I443= | Silent (SNP) | VAF 28/36 reads (78%) | catalogued as COSV58459310; called by muse, varscan2
- DNASE1L1 | c.888T>C p.P296= | Silent (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- EPHB6 | c.543T>C p.A181= | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- FCRL5 | c.2493G>A p.E831= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as rs1313080199; called by muse, mutect2
- FSD2 | c.1407T>A p.P469= | Silent (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- GAA | c.1047C>T p.S349= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs138262940; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GLG1 | c.1599A>G p.L533= | Silent (SNP) | VAF 23/31 reads (74%) | called by muse, mutect2, varscan2
- HAGHL | c.777C>T p.T259= (on ENST00000341413; = p.P222S on NM_032304.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs199808048; called by muse, mutect2, varscan2
- HAND2 | c.645C>G p.L215= | Silent (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- HCN2 | c.684C>T p.I228= | Silent (SNP) | VAF 43/49 reads (88%) | called by muse, mutect2, varscan2
- LDHD | c.243G>A p.L81= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- LRIG3 | c.2688C>T p.D896= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as rs1002749441; called by muse, mutect2, varscan2
- MAN2B1 | c.2982C>T p.P994= | Silent (SNP) | VAF 100/263 reads (38%) | called by muse, mutect2, varscan2
- MYF6 | c.468G>A p.K156= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV57352601, COSV57353668; called by muse, mutect2, varscan2
- NUP205 | c.5025G>C p.L1675= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- OR8K3 | c.430C>T p.L144= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2
- PCNX3 | c.3762C>T p.I1254= | Silent (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- PRND | c.78G>A p.T26= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs751374177, COSV59896428; called by muse, mutect2, varscan2
- RARA | c.546G>A p.P182= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs200393055; called by mutect2, varscan2
- RBM12B | c.1953C>T p.F651= | Silent (SNP) | VAF 24/188 reads (13%) | called by muse, mutect2, varscan2
- SERINC4 | c.1150C>T p.L384= | Silent (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2
- SIMC1 | c.1710G>T p.L570= (on ENST00000443967 / NM_001308196.1; = p.L155= on NM_198567.5) | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- TACC2 | c.3381C>T p.A1127= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs140254775; called by muse, mutect2, varscan2
- TSHZ3 | c.1779T>C p.S593= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- WDR17 | c.327C>A p.I109= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV54568591; called by muse, mutect2, varscan2
- ZHX1 | c.69G>A p.E23= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs770374909; called by muse, mutect2, varscan2
- ZNF536 | c.3630G>A p.Q1210= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs1377513217; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498992 G>A | 5'Flank (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- FCRL2 | c.884-114G>A | Intron (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- OR52A4P | n.650G>C | RNA (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- TMEM167B | chr1:109100392 G>A | 3'Flank (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
